Somatic mutation profile of tumor specimen TCGA-FG-A60K-01A (aliquot TCGA-FG-A60K-01A-11D-A29Q-08) from TCGA case TCGA-FG-A60K, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.1 years (12,445 days).
Specimen TCGA-FG-A60K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 956f3f6e-37aa-457e-bad4-b299d74c472a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A60K-10A (Blood Derived Normal), aliquot TCGA-FG-A60K-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5428a978-5324-406f-9f89-ddba31ecbc22

The open-access MAF lists 21 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 17, Frame Shift Ins 2, Translation Start Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/69 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CLEC4D | c.516T>G p.N172K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV55228642; called by muse, mutect2, varscan2
- DOCK6 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV52948797; called by muse, mutect2
- GLIS2 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV52109997; called by muse, mutect2, varscan2
- GTF2H4 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52558447; called by muse, mutect2, varscan2
- KIF25 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs150821798; called by muse, varscan2
- MED12 | c.2650C>G p.L884V | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61331912; called by muse, mutect2, varscan2
- PLB1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs769728588, COSV59822828; called by muse, mutect2, varscan2
- PLEKHG6 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV50599446; called by muse, mutect2, varscan2
- PPOX | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.178); catalogued as COSV57087739; called by muse, mutect2
- R3HDM1 | c.2562C>G p.N854K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.343); catalogued as COSV51522992; called by muse, mutect2, varscan2
- RC3H1 | c.2264A>T p.H755L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.986); catalogued as COSV51199221; called by muse, mutect2
- RPS6KA2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV99692013; called by muse, mutect2
- SCARA5 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1434449808, COSV57276567; called by muse, mutect2
- SLC35E4 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55898914; called by muse, mutect2, varscan2
- TNF | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69304416; called by muse, mutect2, varscan2
- TTBK2 | c.793T>G p.L265V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51158885; called by muse, mutect2, varscan2
- ZMYM3 | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as COSV58737160; called by muse, mutect2, varscan2
- CCNA1 | c.539dup p.N180Kfs*17 | Frame Shift Ins (INS) | VAF 36/127 reads (28%) | called by mutect2, pindel, varscan2
- CIC | c.4389_4392dup p.R1465Afs*50 | Frame Shift Ins (INS) | VAF 25/47 reads (53%) | called by mutect2, pindel, varscan2
- RIPOR3 | c.873G>A p.T291= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs769294751, COSV50386105, COSV50387364; called by muse, mutect2, varscan2
